Surgical pathology report (de-identified scan), TCGA case TCGA-AA-3831, project TCGA-COAD (Colon Adenocarcinoma), tissue source site Indivumed, specimen TCGA-AA-3831-01A (Primary Tumor).

Light microscopic findings

1. In relation to histology, an advanced carcinoma in block A is visible in the material at hand, severely necrotic here. Tumor cells are classified in relation to a colic adenocarcinoma, specifically characteristic tubular formations, extensive necroses as well numerous nuclear atypia.

The tumor is penetrating all wall layers as well as vessels, consistent with p T 1, L1, V1.

Only granulation tissue is visible in the region of the serosa.

Tumor classification summary:

ICDO-DA-M

8140/3

G 2 - 3

p T 3

L1, V1

p N 0

Consistent with R0

Source: NCI Genomic Data Commons file 9388de2f-e03d-4c0e-9bad-809a3c7bed03 (TCGA-AA-3831.009C3F80-2F13-4B24-90F1-B0EAAC864E66.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).